CCDI case PBCKIW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6eff4416-eb8d-4a6a-a07a-af119dc23896

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 2.7 years (987 days).

Biospecimens (2 samples)
- Sample 0DUIWW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUIX8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
